Gene-level copy-number profile of tumor specimen TCGA-FI-A2EU-01A from TCGA case TCGA-FI-A2EU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-FI-A2EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.833e261d-d303-4bbc-93ad-e47ca166d2c8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2EU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d8463315-6ce5-4404-b8f8-b243e5113b9f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 15,152; copy number 2: 37,819; copy number 3: 6,172; copy number 4: 196; copy number 5: 286; copy number 6: 31; copy number 7: 9; copy number 10: 36; copy number 12: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2EU-01A-11D-A17C-01): tumor purity 0.94, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 366 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,509,397–22,323,331, 27 genes, copy number 5 (within-gene range 3–5): ALPL, LINC02596, RAP1GAP, USP48, AL590103.1, LDLRAD2, HSPG2, AL590556.1, AL590556.2, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1, MIR4418, PPIAP34.
- chr3:169,613,510–169,812,986, 12 genes, copy number 5: AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2.
- chr4:1,550,284–1,580,253, 2 genes, copy number 5: AC147067.2, AC147067.1.
- chr5:38,258,409–38,465,480, 1 gene, copy number 5 (within-gene range 1–5): EGFLAM.
- chr5:38,345,347–39,524,726, 21 genes, copy number 5: EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104.
- chr5:53,089,016–53,683,338, 8 genes, copy number 5: AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4.
- chr6:23,854,139–24,666,930, 15 genes, copy number 5: AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2.
- chr6:32,517,353–32,589,848, 4 genes, copy number 12: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr10:72,053,294–81,875,133, 234 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr10:82,207,620–82,232,920, 3 genes, copy number 6: AC010157.2, AC010157.1, NRG3-AS1.
- chr19:9,498,678–10,074,135, 30 genes, copy number 5 (within-gene range 4–5): AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT, ZNF121, ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589.
- chr21:24,306,939–25,135,247, 9 genes, copy number 7 (within-gene range 3–7): LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1.

Autosomal genes at a single copy (total copy number 1): 14,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
